Somatic mutation profile of tumor specimen MP2PRT-PASDPC-TMP1-A (aliquot MP2PRT-PASDPC-TMP1-A-1-0-D-A80I-36) from MP2PRT case MP2PRT-PASDPC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.3 years (1,940 days).
Specimen MP2PRT-PASDPC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f3ec4c77-73d7-4a53-9ac4-4b208256dec1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASDPC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASDPC-NB1-A-1-0-D-A80I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/470f978c-ed9a-4f49-8518-f0339691f7af

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 6, Silent 3, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DCAF4L2 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 106/401 reads (26%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as rs1202467100, COSV100151058, COSV60479030; called by muse, mutect2, varscan2
- PCDHA8 | c.2056G>A p.V686I | Missense Mutation (SNP) | VAF 257/533 reads (48%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs375387773; called by muse, mutect2, varscan2
- TUBA3C | c.550C>A p.P184T | Missense Mutation (SNP) | VAF 220/538 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV67139094; called by muse, mutect2, varscan2
- ZNF676 | c.557C>T p.S186L (on ENST00000650058; = p.S154L on NM_001001411.3) | Missense Mutation (SNP) | VAF 21/346 reads (6%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.918); catalogued as rs754813419, COSV68093483; called by muse, mutect2
- OR1Q1 | c.326T>C p.V109A | Missense Mutation (SNP) | VAF 14/465 reads (3%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2
- TTC9C | c.77_78insCGA p.D26dup | In Frame Ins (INS) | VAF 216/446 reads (48%) | called by mutect2, pindel, varscan2
- UTS2R | c.196G>A p.V66M | Missense Mutation (SNP) | VAF 296/634 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.066); called by muse, varscan2
- CELSR1 | c.6210C>T p.F2070= | Silent (SNP) | VAF 101/327 reads (31%) | catalogued as rs371374031; called by muse, mutect2, varscan2
- IGKV1OR2-108 | chr2:113406871 del TTCACAGTG | Silent (DEL) | VAF 61/116 reads (53%) | called by pindel, varscan2
- MYH9 | c.270G>A p.T90= | Silent (SNP) | VAF 135/303 reads (45%) | catalogued as rs780422191; called by muse, mutect2, varscan2
